HCMI case HCM-BROD-0693-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f1332ba6-887b-45ec-846b-1180cbfd66b7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,222 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -4 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 30 days; Days to treatment end: 268 days.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 31 days; Days to treatment end: 73 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 296 days; Days to treatment end: 296 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease.

Follow-up (3 entries)
- Days to follow up: 163 days; Karnofsky performance status: 80.
- Days to follow up: 404 days (1.1 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 0, day 200.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 31.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0693-C71-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-BROD-0693-C71-01A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 87; Percent normal cells: 11; Percent necrosis: 1; Percent stromal cells: 13; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0693-C71-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 76; Percent tumor nuclei: 88; Percent normal cells: 10; Percent necrosis: 1; Percent stromal cells: 13; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0693-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0693-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
